Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7232, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7232-01A (Primary Tumor).

[page 1 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

PROSTATE GLAND, RADICAL PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA.
- Gleason score 4+5=9.
- Multifocal, involving both lobes.
- Dominant nodule, 2.5 cm in maximum dimension.
- MARGIN STATUS: NEGATIVE.
- Closest margin, right apex, 0.07 cm.
- LYMPHOVASCULAR INVASION: NOT IDENTIFIED.
- PERINEURAL INVASION: PRESENT.
- EXTRAPROSTATIC EXTENSION: PRESENT.
- SEMINAL VESICLE INVASION: PRESENT.

PATHOLOGIC TUMOR STAGING SUMMARY:

- Primary tumor: pT3b (tumor invades seminal vesicle).
- Regional lymph nodes: pNX.
- Distant metastasis: pMX.
- Pathologic stage: III.
- Margin status: R0 (closest, right apex at 0.07 cm).
-

[page 2 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Prostate Tumor Staging Information

(data derived from current specimen, staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, [REDACTED])

Procedure:
Specimen type:
Prostate size/weight:

Radical prostatectomy
Prostate gland
5.2 x 3.2 x 3.5 cm, 62 grams

TUMOR FEATURES:

Tumor site:
Tumor quantification:

Multifocal, involving both lobes
Dominant nodule 2.5 cm in greatest dimension; tumor
Involves approximately 70% of the prostate gland
Adenocarcinoma

Histologic type:
Histologic grade:
Primary pattern:
Secondary pattern:
Tertiary pattern:
Total Gleason score:
Lymphovascular invasion:
Perineural invasion:
Extraprostatic extension:
Seminal vesicle invasion:
Treatment effect:

4
5
Not applicable
9
Not identified
Present
Present
Present
Not applicable

Lymph nodes:

None submitted for evaluation

Margin evaluation:
Distance to closest margin:
Other margins:

Right apex, at 0.07 cm
Uninvolved by invasive carcinoma

PATHOLOGIC TUMOR STAGING SUMMARY:

Primary tumor:
Regional lymph nodes:
Distant metastasis:
Pathologic stage:
Margin status:

pT3b (tumor invades seminal vesicle)
pNX
pMX
III
R0 (closest margin, right apex at 0.07 cm)

Additional findings:

High grade prostatic intraepithelial neoplasia

[page 3 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

Prostatectomy

Clinical History/Operative Dx:

Prostate cancer.

Gross Description:

The specimen is labeled prostate and is received without fixative. It consists of a prostatectomy specimen which weighs 62 grams. The prostate gland measures 5.2 x 3.2 x 3.5 cm and includes a 4 x 1.5 x 0.8 cm right seminal vesicle, a 2 cm segment of right vas deferens, a 1.7 cm segment of left vas deferens, and a 3.8 x 1.5 x 1 cm left seminal vesicle. The right anterior surface of the prostate is inked blue, the left anterior surface is inked green, and the posterior surface is inked black. The prostatic apex, bladder neck, and seminal vesicles/vasa are trimmed. The prostate is serially sectioned from apex to bladder neck. The prostatic gland parenchyma shows bright yellow discoloration in the apical portion of the right prostate and bright yellow discoloration extends throughout most of the posterior gland bilaterally. There is bulging yellow nodularity in the periurethral region. Representative prostatic tissue is obtained for research purposes. Also in the specimen container are three additional tubular portions of pink-tan tissue suggestive of portions of vasa varying from 0.5-2.5 cm in length and up to 0.7 cm in diameter. Representative sections are submitted. Section summary: A1-A2) apical margin right prostate, A3-A4) apical margin left prostate, A5) right bladder neck, A6) left bladder neck, A7) surgical margin right vas deferens, right seminal vesicle, A8) surgical margin left vas deferens, left seminal vesicle, A9-A22) prostate, apex-bladder neck, A23) separate tissue,

Microscopic Description:

Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Source: NCI Genomic Data Commons file dd85b86a-1648-4153-8eab-f0d477f180ae (TCGA-HC-7232.D5B6E727-43D6-4D27-A7AE-D89C046EF4EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).